Surgical pathology report (de-identified scan), TCGA case TCGA-36-2543, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site BC Cancer Agency, specimen TCGA-36-2543-01A (Primary Tumor).

[page 1 of 2]
Surgical Pathology Consultation Report

TCGA-36-2543

Case Number:

Collect Date:

Receive Date:

Date Reported:

Patient's Name:

MRN:

PHN:

DOB/Gender:

Ordering
Physician:

Final Diagnosis:

A. Omentum: extensive involvement by high-grade serous carcinoma; the appearance is consistent with peritoneal, ovarian, tubal, or endometrial origin

B. Washings: positive for malignant cells

Specimens Received:

A: omentum

Gross Description:

The specimen is received in one container labelled with the patient's name and OMENTUM, and this consists of a piece of omental tissue that weighs 158 g. The

[page 2 of 2]
specimen measures 35 cm X 7 cm X 2 cm (thickness). There are multiple solid areas present within the omental tissue. The largest one measures up to 7 cm in greatest dimensions. The second largest one measures up to 4 cm in greatest dimensions. The cut surfaces of the solid areas are white, firm, and uniform. Representative sections are submitted as follows:

A1-A3 -the largest nodule

A4 -second largest nodule

A5-A6 -smaller solid areas

A7 -omental tissue with less tumour involvement

Source: NCI Genomic Data Commons file f1a5433f-eaee-4b81-ace3-98f499db6fb9 (TCGA-36-2543.EC25AC8E-1A07-459B-A986-C78EDFFF88C0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).